Somatic mutation profile of tumor specimen TCGA-IB-7887-01A (aliquot TCGA-IB-7887-01A-11D-2154-08) from TCGA case TCGA-IB-7887, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.9 years (22,990 days).
Specimen TCGA-IB-7887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27fed430-09da-47db-bd53-4a73d42219c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7887-10A (Blood Derived Normal), aliquot TCGA-IB-7887-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b728df73-c1a3-4fb5-b0c6-c08817435649

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 4, Frame Shift Ins 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 21/169 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 41/275 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DCHS1 | c.684T>G p.Y228* | Nonsense Mutation (SNP) | VAF 118/726 reads (16%) | catalogued as COSV100201338; called by muse, mutect2, varscan2
- DGKB | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 72/438 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV51812280, COSV99335545; called by muse, mutect2, varscan2
- DLGAP4 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs779644254, COSV100210688; called by muse, mutect2, varscan2
- FBN3 | c.8374C>T p.Q2792* | Nonsense Mutation (SNP) | VAF 48/377 reads (13%) | catalogued as COSV53664432; called by muse, mutect2, varscan2
- FLG | c.9593T>G p.V3198G | Missense Mutation (SNP) | VAF 253/2090 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs143183339; called by muse, mutect2, varscan2
- FOXJ2 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99367995; called by muse, mutect2
- GLI3 | c.3745T>G p.C1249G | Missense Mutation (SNP) | VAF 65/630 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV101229671; called by muse, mutect2
- IGSF1 | c.3868C>T p.R1290* | Nonsense Mutation (SNP) | VAF 270/1850 reads (15%) | catalogued as rs749977306, COSV63840206; called by muse, mutect2, varscan2
- KRT31 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 88/642 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV99289297; called by muse, mutect2, varscan2
- PES1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 72/513 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs750067678, COSV100072936; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 62/448 reads (14%) | catalogued as rs778683789; called by mutect2, varscan2
- SACS | c.11821C>T p.Q3941* | Nonsense Mutation (SNP) | VAF 88/798 reads (11%) | catalogued as COSV101207125; called by muse, mutect2, varscan2
- SEMG2 | c.1320G>C p.E440D | Missense Mutation (SNP) | VAF 89/642 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV101033907, COSV65647334; called by muse, mutect2, varscan2
- SSMEM1 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 91/806 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99927556; called by muse, mutect2, varscan2
- TAF5L | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 63/920 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1318439520, COSV99272478, COSV99272833; called by muse, mutect2
- TFB2M | c.1163T>A p.L388Q | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100830413; called by muse, mutect2, varscan2
- TOGARAM1 | c.2381T>C p.F794S | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.57); catalogued as COSV100817712; called by muse, mutect2, varscan2
- TTC3 | c.5851G>A p.A1951T | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100694900; called by muse, mutect2, varscan2
- ZYG11B | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 49/406 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs151077871; called by muse, mutect2, varscan2
- CTSB | c.517dup p.Y173Lfs*2 | Frame Shift Ins (INS) | VAF 61/483 reads (13%) | called by mutect2, pindel, varscan2
- FAM117B | c.1499dup p.N500Kfs*8 | Frame Shift Ins (INS) | VAF 134/1083 reads (12%) | called by mutect2, pindel, varscan2
- CLVS1 | c.408C>T p.Y136= | Silent (SNP) | VAF 52/369 reads (14%) | catalogued as rs758197932, COSV57981019, COSV57981660; called by muse, mutect2, varscan2
- GLI3 | c.3744C>T p.P1248= | Silent (SNP) | VAF 66/633 reads (10%) | catalogued as rs776336534, COSV101229672; called by muse, mutect2
- MBOAT7 | c.258C>T p.F86= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1172704624, COSV99824524; called by muse, mutect2
- OR10K2 | c.618C>T p.V206= | Silent (SNP) | VAF 45/434 reads (10%) | catalogued as COSV100149354; called by muse, mutect2, varscan2
- UNC13A | c.1464C>T p.I488= | Silent (SNP) | VAF 90/734 reads (12%) | catalogued as rs551065041, COSV53194354; called by muse, mutect2, varscan2
- NRG1 | c.502+30998G>A | Intron (SNP) | VAF 50/387 reads (13%) | catalogued as rs148668339; called by muse, mutect2, varscan2
